Somatic mutation profile of tumor specimen TARGET-10-PARTZJ-09A (aliquot TARGET-10-PARTZJ-09A-01D) from TARGET case TARGET-10-PARTZJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,062 days).
Specimen TARGET-10-PARTZJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 491c76dc-4fc3-4f98-aedd-9854132306c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTZJ-10A (Blood Derived Normal), aliquot TARGET-10-PARTZJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/542acb7a-5dad-4e3d-8548-32409076bc30

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DIP2C | c.4094C>T p.P1365L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.435); catalogued as COSV55177206; called by muse, mutect2
- DRICH1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs566974806; called by muse, mutect2, varscan2
- RYR3 | c.6304C>T p.R2102* | Nonsense Mutation (SNP) | VAF 51/123 reads (41%) | catalogued as COSV101215034, COSV66779787; called by muse, mutect2, varscan2
- TFCP2L1 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374243132; called by muse, mutect2, varscan2
- ACSL3 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- DZANK1 | c.579T>G p.C193W | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- GGT5 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TACC1 | c.*3930_*3963del | 3'UTR (DEL) | VAF 16/63 reads (25%) | called by pindel, varscan2*
